Somatic mutation profile of tumor specimen TCGA-EI-6917-01A (aliquot TCGA-EI-6917-01A-11D-1924-10) from TCGA case TCGA-EI-6917, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 33.2 years (12,113 days).
Specimen TCGA-EI-6917-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09fc8391-8a49-4bf7-a200-36c39c750216.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6917-10A (Blood Derived Normal), aliquot TCGA-EI-6917-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/509d59ea-b22c-42bc-8937-147fa7557947

The open-access MAF lists 6,352 somatic variants for this specimen: 4,605 protein-altering or splice-affecting, 1,254 silent, 493 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,997, Silent 1,254, Nonsense Mutation 505, 3'UTR 217, Intron 134, RNA 68, Splice Site 51, 5'UTR 38, Splice Region 34, 3'Flank 23, 5'Flank 13, Frame Shift Ins 9.

Variants (750 of 6,352; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.17314C>T p.R5772* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as rs749956288, COSV67984106; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.5188C>T p.R1730* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as rs764389018, CM990211, COSV53730827; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CA8 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs387906598, CM118190, COSV58771796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CBS | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs773734233, CM990342, COSV61442631; ClinVar: pathogenic; called by mutect2, varscan2
- CEP83 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as rs1207804224, COSV51574274; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHMP2B | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as rs63751048, CM067363, COSV55461926; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- CREBBP | c.3832G>A p.E1278K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs267606752, CM030210, COSV52120305; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66706044; called by muse, mutect2, varscan2
- DIS3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 23/87 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs139907646, COSV66705997; called by muse, mutect2, varscan2
- DNMT1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs751093624, COSV61576638; called by muse, mutect2, varscan2
- DUOX2 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs119472029, CM053838; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERCC6 | c.1954C>T p.R652* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as rs767247987, CM099974, COSV63387759; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EVC2 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as rs137852924, CM030650, COSV100186396; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F11 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.519); catalogued as rs771896253, CM062627, COSV53001857; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs137854467, CM940756, COSV57315297; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GBE1 | c.1570C>T p.R524* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as rs137852888, CM960707; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRIN2B | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1085307547, COSV74205114; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LMBRD1 | c.1222C>T p.R408* (on ENST00000649011; = p.R386* on NM_018368.4) | Nonsense Mutation (SNP) | VAF 30/132 reads (23%) | catalogued as rs1380343985, COSV65296997; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as rs727504317, CM076269, COSV61068427, COSV61072298; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP2K4 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 22/47 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62254615; called by muse, mutect2, varscan2
- MAP3K1 | c.3989C>T p.S1330L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1287268127, COSV68121509, COSV68122713; called by muse, mutect2, varscan2
- MLH1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63751194, CM011411, CM064120, CS105415, COSV51615553, COSV51616044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 44/161 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1466678870, COSV100647812, COSV62201290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NGLY1 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 32/112 reads (29%) | catalogued as rs146140738, COSV54984601; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OTC | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs66550389, CM062966, CM062967, CM910275, COSV50000649, COSV50002957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH19 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064794763, COSV55261875; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 38/72 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CB | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 22/94 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs1451809865, COSV56683754; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.11524C>T p.R3842* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as rs746471701, CM051192, COSV64380558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, varscan2
- PPM1D | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | hotspot (GDC flag); catalogued as rs759850701, COSV59954557; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 26/127 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 69/220 reads (31%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAD21 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs775266057, CM152293; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RP2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556318633, CM033008, CM077334, COSV54460861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RPL21 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as rs587777527, CM115086, COSV55388511; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RRM2B | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.597); catalogued as rs515726186, CM0910814, COSV52566610; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RUNX1 | c.530G>A p.R177Q (on ENST00000344691 / NM_001001890.3; = p.R204Q on NM_001754.5) | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1569061762, CM093278, COSV55866469, COSV55875660, COSV55875973; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.10046C>T p.S3349L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs786205455, COSV63682165; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SELENON | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs368377980, COSV62524851; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SLC26A4 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370588279, CM030956, COSV55914262; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC4A1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as rs750930293, CM1212125, COSV52258614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 44/151 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV61687696; called by muse, mutect2, varscan2
- TGFB2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as rs869025531, CM1210056, COSV65109013, COSV65110174; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TGFBR1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111854391, CM061221, COSV66624834; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.70546C>T p.R23516* (on ENST00000591111; = p.R16092* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as rs1553603394, COSV59899993; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.69917G>A p.R23306H (on ENST00000591111; = p.R15882H on NM_003319.4) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | PolyPhen possibly damaging (0.754); catalogued as rs765512476, COSV100604375, COSV60015763; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.40399C>T p.R13467* (on ENST00000591111; = p.R6043* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as rs1060500405, COSV59862588; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 35/116 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55289831; called by muse, mutect2, varscan2
- A2ML1 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs758305694, COSV100229195, COSV55290676; called by muse, mutect2, varscan2
- A2ML1 | c.3466C>T p.L1156F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs915659031, COSV55289840; called by muse, varscan2
- A4GNT | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52628738; called by muse, mutect2, varscan2
- AADACL3 | c.846A>C p.R282S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as COSV60198813; called by muse, mutect2, varscan2
- AASDHPPT | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV53788915; called by muse, mutect2, varscan2
- AASDHPPT | c.299A>C p.N100T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV53788924; called by muse, mutect2, varscan2
- AASS | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777159345, COSV62789761, COSV62789768; called by muse, mutect2, varscan2
- AASS | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431496936, COSV62789773; called by muse, varscan2
- AATK | c.340C>T p.L114F (on ENST00000326724 / NM_001080395.3; = p.L11F on NM_004920.2) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV58687579; called by muse, mutect2, varscan2
- ABAT | c.219T>G p.F73L | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as COSV51622573; called by muse, mutect2, varscan2
- ABCA1 | c.6712A>C p.N2238H | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV66065840; called by muse, mutect2, varscan2
- ABCA1 | c.5283G>T p.K1761N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV66065848; called by muse, mutect2, varscan2
- ABCA10 | c.2773G>T p.D925Y | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV52221323; called by muse, mutect2, varscan2
- ABCA10 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 23/97 reads (24%) | catalogued as COSV52221333, COSV52222468; called by muse, mutect2, varscan2
- ABCA12 | c.6008G>A p.S2003N (on ENST00000272895 / NM_173076.3; = p.S1685N on NM_015657.3) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55957297; called by muse, mutect2, varscan2
- ABCA12 | c.4544G>A p.R1515Q (on ENST00000272895 / NM_173076.3; = p.R1197Q on NM_015657.3) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs774279263, CM1311790, COSV55948366; called by muse, mutect2, varscan2
- ABCA13 | c.2223G>T p.E741D | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as rs765349564, COSV70027732; called by muse, varscan2
- ABCA13 | c.3028G>A p.A1010T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as rs770574570, COSV70027768; called by muse, mutect2, varscan2
- ABCA13 | c.3305C>T p.S1102L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375389053; called by mutect2, varscan2
- ABCA13 | c.7048G>A p.E2350K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV71284578, COSV71286769; called by muse, mutect2, varscan2
- ABCA13 | c.12799G>A p.E4267K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV101291485, COSV68946127; called by muse, mutect2, varscan2
- ABCA5 | c.4901G>A p.R1634Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.994); catalogued as rs374390008; called by muse, mutect2, varscan2
- ABCA5 | c.4427G>A p.R1476Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs750426352, COSV67015792; called by mutect2, varscan2
- ABCA5 | c.1838A>C p.K613T | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as COSV67016581; called by muse, mutect2, varscan2
- ABCA6 | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.063); catalogued as rs756114521, COSV52641162; called by muse, varscan2
- ABCA6 | c.2234T>C p.V745A | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.49); catalogued as COSV52638040; called by muse, mutect2, varscan2
- ABCA7 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54028506; called by muse, mutect2, varscan2
- ABCA8 | c.3770T>G p.F1257C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV52200239; called by muse, varscan2
- ABCA9 | c.4569G>T p.K1523N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as COSV60624028; called by muse, mutect2, varscan2
- ABCA9 | c.4390C>T p.R1464W | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374873743; called by muse, mutect2, varscan2
- ABCA9 | c.2804G>A p.R935Q | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs766035326, COSV60624046; called by muse, mutect2, varscan2
- ABCB1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs754765644, COSV55948559; called by mutect2, varscan2
- ABCB1 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201352027, COSV55949474; called by muse, mutect2, varscan2
- ABCB11 | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.833); catalogued as rs868669576, COSV55589511; called by muse, mutect2, varscan2
- ABCB4 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.113); catalogued as rs377268767; called by muse, mutect2, varscan2
- ABCB5 | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs762495535, COSV68855019, COSV68856812; called by muse, mutect2, varscan2
- ABCB6 | c.2267C>T p.A756V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1251196290, COSV54695517; called by muse, mutect2, varscan2
- ABCC11 | c.744A>T p.Q248H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV62322771; called by muse, varscan2
- ABCC2 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | catalogued as rs529588584, CM035497, COSV64970800; called by muse, varscan2
- ABCC2 | c.3541C>T p.R1181* | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | catalogued as rs1045996985, COSV100966706, COSV64985861; called by muse, mutect2, varscan2
- ABCC8 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs200687571, CM113479, CM118597, COSV56848525; called by muse, mutect2, varscan2
- ABCD4 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as rs778245156, COSV53992097; called by muse, mutect2, varscan2
- ABCE1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as COSV56847048; called by muse, mutect2, varscan2
- ABCE1 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs550948053, COSV56846273; called by muse, mutect2, varscan2
- ABCG1 | c.717C>A p.F239L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV59203545; called by mutect2, varscan2
- ABCG4 | c.1811G>A p.S604N | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1233138623, COSV56643403; called by muse, mutect2, varscan2
- ABHD17C | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.406); catalogued as rs200549811, COSV51917334, COSV51918242; called by muse, mutect2, varscan2
- ABL2 | c.2277G>T p.K759N (on ENST00000502732 / NM_007314.4; = p.K744N on NM_005158.5) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV61013328; called by muse, mutect2, varscan2
- ABL2 | c.1582G>A p.D528N (on ENST00000502732 / NM_007314.4; = p.D513N on NM_005158.5) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs754261724, COSV61013345; called by muse, mutect2, varscan2
- ABLIM2 | c.1337C>T p.S446L (on ENST00000341937 / NM_001130084.2; = p.S394L on NM_032432.5) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs781433817, COSV56403452; called by muse, mutect2, varscan2
- ABRA | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs551422006, COSV100357667, COSV61732308; called by muse, mutect2, varscan2
- AC004593.2 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV56091438; called by muse, mutect2, varscan2
- AC026786.1 | c.474G>T p.R158S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.48); catalogued as rs868005962; called by muse, mutect2, varscan2
- AC090517.4 | c.1468A>C p.K490Q | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1451780434, COSV50996580; called by muse, mutect2, varscan2
- AC090517.4 | c.1321A>C p.K441Q | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50996597; called by muse, mutect2, varscan2
- AC090517.4 | c.279A>G p.I93M | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as COSV50996612; called by muse, mutect2, varscan2
- AC092143.1 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs777149755, COSV59247734; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC109583.1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV59350606; called by muse, mutect2, varscan2
- AC126283.2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773085612, CM161603, COSV67098504; called by muse, mutect2, varscan2
- ACACB | c.1337G>T p.R446I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV58128531; called by muse, mutect2, varscan2
- ACACB | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs753617014, COSV58128757; called by muse, mutect2, varscan2
- ACADL | c.589C>A p.L197I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.766); catalogued as COSV52053171; called by muse, mutect2, varscan2
- ACADM | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.358); catalogued as COSV63720044, COSV63720242; called by muse, mutect2, varscan2
- ACAN | c.6869C>T p.A2290V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.061); catalogued as COSV61359672; called by muse, mutect2, varscan2
- ACBD7 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62252463, COSV62252626; called by muse, mutect2, varscan2
- ACER3 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53598663; called by muse, mutect2, varscan2
- ACER3 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as rs782329790, COSV53598670; called by muse, mutect2, varscan2
- ACOT6 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV66968940; called by muse, mutect2, varscan2
- ACP7 | c.1030T>C p.Y344H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58699164; called by muse, mutect2, varscan2
- ACRV1 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV59754740; called by mutect2, varscan2
- ACSM1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs369139443; called by muse, mutect2, varscan2
- ACSM4 | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs1412358684, COSV68067591, COSV68067628; called by muse, mutect2, varscan2
- ACTL7B | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65927271; called by muse, mutect2, varscan2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ACTR2 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.804); catalogued as rs1440834418, COSV53200285; called by muse, mutect2, varscan2
- ACTR2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV53200653; called by muse, mutect2, varscan2
- ACVR1C | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs775081249, COSV54643616; called by muse, mutect2, varscan2
- ACVR2A | c.979A>C p.N327H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54021593; called by muse, mutect2, varscan2
- ADAD1 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56643133; called by muse, mutect2, varscan2
- ADAD2 | c.1694A>G p.D565G (on ENST00000315906 / NM_001145400.2; = p.D647G on NM_139174.4) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.493); catalogued as COSV51893260; called by muse, mutect2, varscan2
- ADAM12 | c.2158C>A p.L720I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as COSV100901599; called by muse, mutect2, varscan2
- ADAM12 | c.1840C>A p.L614M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV64105733, COSV64108824; called by muse, mutect2, varscan2
- ADAM15 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.531); catalogued as rs372429897; called by mutect2, varscan2
- ADAM18 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs758265669, COSV55844012; called by muse, mutect2, varscan2
- ADAM2 | c.190A>C p.N64H | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.722); catalogued as rs1248751167, COSV55861499; called by muse, mutect2, varscan2
- ADAM23 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV52213997; called by muse, mutect2, varscan2
- ADAM28 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1190390417, COSV56100063; called by muse, mutect2, varscan2
- ADAM30 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs781229975, COSV65560969; called by muse, mutect2, varscan2
- ADAM32 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as COSV65947950; called by muse, mutect2, varscan2
- ADAM9 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs760058275, COSV65946602; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1305T>G p.D435E | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56475051; called by muse, mutect2, varscan2
- ADAMTS1 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as rs944862656, COSV53169549; called by muse, mutect2
- ADAMTS1 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373807387; called by mutect2, varscan2
- ADAMTS14 | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.617); catalogued as rs780861873, COSV64601619; called by muse, mutect2, varscan2
- ADAMTS16 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775874041, COSV56987073, COSV56989155; called by muse, varscan2
- ADAMTS16 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs115892769; called by muse, varscan2
- ADAMTS16 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760889068, COSV56984347; called by muse, mutect2, varscan2
- ADAMTS18 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs774713566, COSV51406679; called by mutect2, varscan2
- ADAMTS19 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 31/138 reads (22%) | catalogued as COSV50731882; called by muse, mutect2, varscan2
- ADAMTS20 | c.2875G>T p.E959* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV67130559; called by muse, mutect2, varscan2
- ADAMTS20 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV67129565; called by muse, mutect2, varscan2
- ADAMTS6 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV66859266; called by muse, mutect2, varscan2
- ADAMTS7 | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs3825828, COSV66306973, COSV66309919; called by muse, mutect2, varscan2
- ADAMTS9 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.692); catalogued as rs779284125, COSV55778559; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1345545620, COSV65887938; called by muse, mutect2, varscan2
- ADCY10 | c.1503G>T p.K501N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs1415277884, COSV100896638, COSV63240393; called by muse, mutect2, varscan2
- ADCY2 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57866908; called by muse, mutect2
- ADCY9 | c.4027G>A p.E1343K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.408); catalogued as rs1368722853, COSV53574571; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV58443297; called by muse, mutect2, varscan2
- ADD2 | c.92A>G p.Y31C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV52460008; called by muse, mutect2, varscan2
- ADD3 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 25/101 reads (25%) | catalogued as COSV53322006; called by muse, mutect2, varscan2
- ADGB | c.444G>T p.K148N | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV58858333; called by muse, mutect2, varscan2
- ADGB | c.3431C>T p.A1144V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62224693; called by muse, mutect2, varscan2
- ADGRA3 | c.3881G>A p.S1294N | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770969743, COSV51562545, COSV99292839; called by muse, mutect2, varscan2
- ADGRA3 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.535); catalogued as rs746516223, COSV51562557; called by muse, mutect2, varscan2
- ADGRB3 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs141698131; called by mutect2, varscan2
- ADGRB3 | c.4161C>A p.F1387L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV53242226; called by muse, mutect2, varscan2
- ADGRD1 | c.967-1G>T p.X323_splice | Splice Site (SNP) | VAF 14/67 reads (21%) | catalogued as COSV55443987, COSV55456936; called by muse, mutect2, varscan2
- ADGRE1 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51674946; called by muse, mutect2, varscan2
- ADGRF1 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV100982672, COSV64799978; called by muse, mutect2, varscan2
- ADGRF2 | c.1240G>T p.E414* (on ENST00000296862 / NM_001368115.2; = p.E346* on NM_153839.7) | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV57288011; called by muse, mutect2, varscan2
- ADGRF3 | c.320G>A p.G107E (on ENST00000311519 / NM_001145168.1; = p.G48E on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV61050006; called by muse, mutect2, varscan2
- ADGRG2 | c.953T>C p.M318T (on ENST00000379869 / NM_001079858.3; = p.M315T on NM_005756.4) | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV61338704; called by muse, mutect2, varscan2
- ADGRG4 | c.3387C>A p.F1129L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54954841; called by muse, mutect2, varscan2
- ADGRG6 | c.3113C>T p.A1038V | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV51590968; called by muse, mutect2, varscan2
- ADGRG7 | c.2038T>G p.F680V | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV56295949; called by muse, mutect2, varscan2
- ADGRL2 | c.3202C>T p.L1068F (on ENST00000370717 / NM_001366005.1; = p.L1055F on NM_012302.4) | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54664961; called by muse, mutect2, varscan2
- ADGRL3 | c.4273G>A p.E1425K (on ENST00000506720 / NM_001322402.2; = p.E1314K on NM_015236.6) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV72230153; called by muse, mutect2, varscan2
- ADGRV1 | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); catalogued as COSV67984032; called by muse, mutect2, varscan2
- ADGRV1 | c.1730T>C p.I577T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1458313406, COSV67984036; called by muse, mutect2, varscan2
- ADGRV1 | c.2466C>A p.F822L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67984094; called by muse, mutect2, varscan2
- ADGRV1 | c.3866C>T p.S1289F | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV67984099; called by muse, mutect2, varscan2
- ADGRV1 | c.14404C>T p.R4802* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as rs1236715896, CM0911268, COSV67978996; called by muse, mutect2, varscan2
- ADH5 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 21/127 reads (17%) | catalogued as rs191189722; called by muse, mutect2, varscan2
- ADNP | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV62424720; called by muse, mutect2, varscan2
- ADNP | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV62424517; called by muse, mutect2, varscan2
- ADNP2 | c.732G>T p.E244D | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.39); catalogued as COSV51538282, COSV51541247; called by muse, mutect2, varscan2
- ADRA2C | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV57467191, COSV57468198; called by muse, mutect2, varscan2
- AEBP1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV56256086, COSV56257213; called by muse, mutect2, varscan2
- AEBP1 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs75175945; called by mutect2, varscan2
- AFDN | c.131G>T p.R44I | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60043522; called by muse, mutect2, varscan2
- AFF3 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57852265; called by muse, mutect2
- AFF4 | c.3436C>T p.R1146C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755303727, COSV54793041; called by muse, varscan2
- AFF4 | c.3369C>A p.F1123L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV54793230; called by muse, varscan2
- AFM | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV56919927; called by muse, mutect2, varscan2
- AGBL1 | c.1195G>T p.D399Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66855080; called by muse, mutect2, varscan2
- AGBL1 | c.1559G>T p.R520I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.851); catalogued as COSV66856573; called by muse, mutect2, varscan2
- AGBL3 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as rs746965087, COSV51950655; called by muse, mutect2, varscan2
- AGER | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV66719064; called by muse, mutect2, varscan2
- AGO4 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV64617053; called by muse, mutect2, varscan2
- AGR3 | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100124073, COSV60037880; called by muse, mutect2, varscan2
- AGTPBP1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61271070; called by muse, mutect2, varscan2
- AGXT2 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51485948; called by muse, mutect2, varscan2
- AHCTF1 | c.5885A>G p.D1962G (on ENST00000366508; = p.D1936G on NM_015446.5) | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as rs775132534, COSV58249222; called by muse, mutect2, varscan2
- AHNAK2 | c.16468C>T p.L5490F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.09); catalogued as COSV60911036, COSV60924087; called by muse, mutect2, varscan2
- AHNAK2 | c.6359A>G p.E2120G | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60914213; called by muse, mutect2, varscan2
- AHNAK2 | c.3135C>A p.D1045E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.147); catalogued as COSV60914219; called by muse, mutect2, varscan2
- AHNAK2 | c.2596G>A p.D866N | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV60914226; called by muse, mutect2, varscan2
- AHRR | c.711G>A p.T237= | Splice Region (SNP) | VAF 16/49 reads (33%) | catalogued as rs370682493; called by muse, mutect2, varscan2
- AIFM2 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57159125; called by muse, mutect2, varscan2
- AJM1 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV56032781; called by muse, mutect2, varscan2
- AK5 | c.1213C>A p.L405I (on ENST00000354567 / NM_174858.3; = p.L379I on NM_012093.4) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.711); catalogued as COSV100642547; called by muse, mutect2, varscan2
- AKAP10 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as COSV56730528; called by muse, mutect2
- AKAP13 | c.4051G>A p.V1351M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs1178627327, COSV63455104; called by muse, mutect2, varscan2
- AKAP14 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as COSV57629981; called by muse, mutect2, varscan2
- AKAP14 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs775150972, COSV57630000; called by muse, mutect2, varscan2
- AKAP4 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1557204135, COSV100654259; called by muse, mutect2, varscan2
- AKAP9 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs864622705, COSV100662522, COSV62344491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKT3 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.413); catalogued as rs751275167, COSV55615010; called by muse, mutect2, varscan2
- AL136295.1 | c.2262C>A p.F754L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55779292; called by muse, mutect2, varscan2
- AL592490.1 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69425975; called by muse, mutect2, varscan2
- AL592490.1 | c.133-1G>A p.X45_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as COSV69425982; called by muse, mutect2
- AL645922.1 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV54960409; called by muse, mutect2, varscan2
- ALAS1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as rs761283191, COSV59627723; called by muse, varscan2
- ALDH1A3 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60901127; called by muse, mutect2, varscan2
- ALDH1A3 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV60901575; called by muse, varscan2
- ALDH1L1 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs201748366, COSV56413477, COSV99857613; called by muse, varscan2
- ALG11 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs754572359, COSV101584404; called by mutect2, varscan2
- ALG13 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 50/87 reads (57%) | catalogued as COSV52638289; called by muse, mutect2, varscan2
- ALG8 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55200212; called by muse, mutect2, varscan2
- ALG8 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55203092; called by muse, mutect2, varscan2
- ALG9 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 66/351 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV67644258; called by muse, mutect2, varscan2
- ALMS1 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs563989825, COSV52508595; called by muse, mutect2, varscan2
- ALMS1 | c.11414G>A p.R3805Q | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.084); catalogued as rs201646938, COSV52508603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPK1 | c.2870C>A p.S957Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51584459, COSV99452703; called by muse, mutect2, varscan2
- ALPK2 | c.6499G>A p.E2167K | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs543965909, COSV64492583, COSV64495347; called by muse, mutect2, varscan2
- ALX1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV57492068; called by muse, mutect2, varscan2
- ALX1 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs150997122, COSV57492012; called by muse, mutect2, varscan2
- ALX4 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as rs144440589; called by mutect2, varscan2
- AMBRA1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV54052960; called by muse, mutect2, varscan2
- AMD1 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV64387323; called by muse, mutect2, varscan2
- AMER1 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 15/19 reads (79%) | catalogued as COSV57659668; called by muse, mutect2, varscan2
- AMER3 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1381313687, COSV58465747; called by muse, mutect2, varscan2
- AMER3 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs767006055, COSV58466413; called by muse, mutect2, varscan2
- AMOTL2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1452558923; called by muse, mutect2, varscan2
- AMPD1 | c.1710G>T p.K570N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1354451905, COSV62415508; called by muse, mutect2, varscan2
- AMY2B | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 118/514 reads (23%) | catalogued as rs770249517, COSV63714026; called by muse, mutect2, varscan2
- AMZ1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs559083782, COSV56686461, COSV56688270; called by muse, mutect2, varscan2
- AMZ2 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV63082869; called by muse, mutect2, varscan2
- ANGPT4 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs376414024, COSV67921220; called by muse, mutect2, varscan2
- ANGPTL1 | c.492A>C p.E164D | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV52366170; called by muse, mutect2, varscan2
- ANK1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs376057905, COSV55880088; called by muse, mutect2, varscan2
- ANK2 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as rs1198719430, COSV52154113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 31/100 reads (31%) | catalogued as rs1162799877, COSV52158299; called by muse, mutect2, varscan2
- ANK2 | c.5245C>A p.P1749T | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.045); catalogued as COSV52158340; called by muse, mutect2, varscan2
- ANK2 | c.9145C>T p.R3049W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201870166, COSV52158351; called by muse, mutect2, varscan2
- ANK2 | c.10975C>T p.R3659C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as rs370699621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.12673C>T p.R4225* (on ENST00000280772 / NM_001320874.2; = p.R849* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV55047406; called by muse, mutect2, varscan2
- ANK3 | c.9770C>A p.P3257H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55055543; called by muse, mutect2, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as rs142673853, COSV55052053; called by muse, mutect2, varscan2
- ANK3 | c.2516C>T p.T839M | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs202156367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKAR | c.2894T>C p.V965A | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV55612045; called by muse, mutect2, varscan2
- ANKFY1 | c.3365G>A p.R1122H (on ENST00000341657 / NM_001330063.2; = p.R1123H on NM_016376.5) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58915174; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs949524880, COSV51841395; called by muse, mutect2, varscan2
- ANKRD1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as rs775584071, COSV65467204, COSV65467871; called by muse, mutect2, varscan2
- ANKRD1 | c.21G>T p.E7D | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV63310967; called by muse, mutect2, varscan2
- ANKRD12 | c.542G>T p.R181I | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50823678, COSV50830284; called by muse, mutect2, varscan2
- ANKRD12 | c.4162C>T p.L1388F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.042); catalogued as COSV50819429, COSV50823705; called by muse, mutect2, varscan2
- ANKRD18B | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as COSV52087590; called by muse, mutect2, varscan2
- ANKRD18B | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.301); catalogued as rs965142417; called by muse, mutect2, varscan2
- ANKRD26 | c.4938G>T p.E1646D | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV101063252, COSV65774544; called by muse, mutect2, varscan2
- ANKRD28 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV67516849; called by muse, mutect2, varscan2
- ANKRD30B | c.3940C>T p.R1314* | Nonsense Mutation (SNP) | VAF 46/154 reads (30%) | catalogued as rs1461097292, COSV57702707; called by muse, mutect2, varscan2
- ANKRD34B | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV58613825; called by muse, mutect2, varscan2
- ANKRD34B | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs759235997, COSV58613830; called by muse, mutect2, varscan2
- ANKRD35 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368812717; called by muse, mutect2, varscan2
- ANKRD45 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 60/261 reads (23%) | catalogued as COSV60960852; called by muse, mutect2, varscan2
- ANKS1A | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.114); catalogued as rs777690613, COSV64460268; called by muse, mutect2, varscan2
- ANKS1B | c.3101G>A p.R1034Q (on ENST00000547776 / NM_152788.4; = p.R200Q on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1207598934, COSV59117456, COSV59118135; called by muse, mutect2, varscan2
- ANKUB1 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as rs530465311, COSV67167339, COSV67167554; called by muse, mutect2, varscan2
- ANKZF1 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750431702, COSV55476317; called by muse, mutect2, varscan2
- ANLN | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs772690246, COSV56075669; called by muse, mutect2, varscan2
- ANO10 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 35/144 reads (24%) | catalogued as COSV52730752, COSV52733131; called by muse, mutect2, varscan2
- ANO2 | c.2159C>T p.S720L (on ENST00000356134 / NM_001278597.3; = p.S724L on NM_001278596.3) | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs764183496, COSV59017542; called by muse, varscan2
- ANO2 | c.1667G>A p.R556Q (on ENST00000356134 / NM_001278597.3; = p.R560Q on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs773771654, COSV59020666; called by mutect2, varscan2
- ANO4 | c.325G>T p.G109* (on ENST00000392977 / NM_001286615.2; = p.G74* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV54594038; called by muse, mutect2, varscan2
- ANO6 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV57660429; called by muse, mutect2, varscan2
- ANOS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs1404298787, COSV52916162; called by muse, mutect2, varscan2
- ANXA1 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV57411127; called by muse, mutect2, varscan2
- ANXA7 | c.784G>A p.D262N (on ENST00000372919 / NM_001320880.2; = p.D240N on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769213073, COSV100873523; called by muse, mutect2, varscan2
- ANXA8 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 79/467 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1427838234; called by muse, mutect2, varscan2
- ANXA9 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs762802671, COSV64484732; called by muse, mutect2, varscan2
- AOPEP | c.2180G>A p.R727Q (on ENST00000375315 / NM_001193329.1; = p.R628Q on NM_032823.5) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs963224133, COSV52987575; called by muse, mutect2, varscan2
- AOX1 | c.2497C>T p.R833C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749776412, COSV65981358; called by muse, mutect2, varscan2
- AOX1 | c.2851C>T p.R951* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as rs140878478; called by muse, mutect2, varscan2
- AP2A2 | c.2478C>A p.F826L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV59960061; called by muse, mutect2, varscan2
- AP3M2 | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as rs1437840697, COSV51528511; called by muse, varscan2
- AP5B1 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs760963217, COSV57502828; called by muse, mutect2, varscan2
- APBB1IP | c.909C>A p.F303L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66131809; called by muse, mutect2, varscan2
- APC | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); catalogued as COSV57340770; called by muse, mutect2, varscan2
- APC | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs377665107, COSV57325234, COSV57340778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.2153T>G p.I718S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57340787; called by muse, mutect2, varscan2
- APC | c.4463T>G p.L1488* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as CM095526, COSV57322122, COSV57323073, COSV57360736; called by muse, mutect2, varscan2
- APCDD1L | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs761771230, COSV100953924, COSV64485971; called by muse, mutect2, varscan2
- APLF | c.878G>T p.R293I | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV58144359; called by muse, mutect2, varscan2
- APOB | c.7388C>T p.A2463V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as COSV51933662; called by muse, mutect2, varscan2
- APOB | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV51922803, COSV51933707; called by muse, varscan2
- APOB | c.1755G>T p.Q585H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV51933716; called by muse, mutect2, varscan2
- APOBEC3G | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.043); catalogued as rs1300478809, COSV68470256; called by muse, mutect2, varscan2
- APP | c.552T>G p.F184L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760249418, COSV60997841; called by muse, mutect2, varscan2
- APTX | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs142133683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQR | c.3053G>A p.R1018Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370660482, COSV50031222; called by muse, mutect2, varscan2
- AQR | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV50029552; called by muse, mutect2, varscan2
- ARAP1 | c.1348C>T p.R450C (on ENST00000393609 / NM_001040118.2; = p.R205C on NM_015242.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs757646454, COSV61990897; called by muse, mutect2, varscan2
- ARAP3 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs752178354, COSV53350397; called by muse, mutect2, varscan2
- ARC | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs759778933, COSV100751659, COSV63078429; called by muse, mutect2, varscan2
- ARF4 | c.296G>T p.R99I | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV57714666, COSV57715913; called by muse, mutect2, varscan2
- ARFGAP1 | c.206A>C p.D69A | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62262936, COSV62263705; called by muse, mutect2, varscan2
- ARFGEF2 | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs763245062, COSV64211973; ClinVar: uncertain significance; called by mutect2, varscan2
- ARHGAP10 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | catalogued as COSV60598492, COSV60598845; called by muse, mutect2, varscan2
- ARHGAP11A | c.2756C>A p.S919* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV55706103; called by muse, mutect2, varscan2
- ARHGAP12 | c.2347C>A p.L783I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60962940; called by muse, mutect2, varscan2
- ARHGAP15 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs781102282, COSV54493411; called by muse, mutect2, varscan2
- ARHGAP18 | c.940A>C p.I314L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV63764306; called by muse, mutect2, varscan2
- ARHGAP20 | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV52810185; called by muse, mutect2, varscan2
- ARHGAP20 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52810200; called by muse, mutect2, varscan2
- ARHGAP21 | c.3480T>C p.Y1160= | Splice Region (SNP) | VAF 13/44 reads (30%) | catalogued as COSV57605158; called by muse, mutect2, varscan2
- ARHGAP21 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as rs1162263953, COSV57603231; called by muse, mutect2, varscan2
- ARHGAP22 | c.1938G>T p.K646N | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV50940567, COSV50970444; called by muse, varscan2
- ARHGAP22 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200717294; called by muse, varscan2
- ARHGAP26 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.985); catalogued as COSV50828468; called by muse, mutect2, varscan2
- ARHGAP27 | c.1236C>A p.F412L (on ENST00000428638 / NM_001282290.1; = p.F71L on NM_199282.3) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV65357660; called by muse, mutect2, varscan2
- ARHGAP29 | c.3673G>T p.E1225* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV53110949; called by muse, mutect2, varscan2
- ARHGAP29 | c.3250C>G p.Q1084E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as COSV53110960; called by muse, mutect2, varscan2
- ARHGAP29 | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs41311170, COSV53110573; called by muse, varscan2
- ARHGAP32 | c.2024G>A p.R675Q (on ENST00000310343 / NM_001378025.1; = p.R326Q on NM_014715.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs141414658; called by mutect2, varscan2
- ARHGAP32 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs867574365; called by muse, mutect2, varscan2
- ARHGAP35 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV68330795; called by muse, mutect2, varscan2
- ARHGAP35 | c.1102A>C p.K368Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV68330803, COSV68330838; called by muse, mutect2, varscan2
- ARHGAP42 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs1049706895, COSV53976118; called by muse, mutect2, varscan2
- ARHGEF15 | c.1577A>G p.D526G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.527); catalogued as COSV62725039; called by muse, mutect2, varscan2
- ARHGEF2 | c.2176C>T p.R726* (on ENST00000361247 / NM_001162383.2; = p.R698* on NM_004723.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV58110469; called by muse, mutect2, varscan2
- ARHGEF26 | c.1693G>T p.D565Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV62845893; called by muse, mutect2, varscan2
- ARHGEF28 | c.4000A>G p.R1334G | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs762965898, COSV55254790; called by muse, mutect2, varscan2
- ARHGEF3 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1181969990, COSV58178788; called by muse, varscan2
- ARHGEF3 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.154); catalogued as rs564333803, COSV58178796; called by muse, varscan2
- ARHGEF33 | c.1054-1G>A p.X352_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as COSV67256813; called by mutect2, varscan2
- ARHGEF7 | c.2366C>T p.S789F (on ENST00000375741 / NM_001113511.2; = p.S768F on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV54542502; called by muse, mutect2, varscan2
- ARHGEF9 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.097); catalogued as rs1203752009, COSV53637533; called by muse, mutect2, varscan2
- ARHGEF9 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53634433; called by muse, mutect2, varscan2
- ARID1B | c.3963T>G p.S1321R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV51659724; called by muse, mutect2, varscan2
- ARID2 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV57599503; called by muse, mutect2, varscan2
- ARID2 | c.1716-1G>A p.X572_splice | Splice Site (SNP) | VAF 17/71 reads (24%) | catalogued as COSV57599884, COSV57606933, COSV57609109; called by muse, mutect2, varscan2
- ARID3C | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.99); PolyPhen benign (0.034); catalogued as rs557801494, COSV52407146; called by muse, mutect2, varscan2
- ARID5B | c.3410C>T p.S1137F | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99689472; called by muse, mutect2, varscan2
- ARIH1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs1259128502, COSV65911454; called by muse, mutect2, varscan2
- ARL1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1033216289, COSV55370222; called by muse, mutect2, varscan2
- ARL1 | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs1318906358, COSV55370232; called by muse, mutect2, varscan2
- ARL2 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs746518542; called by mutect2, varscan2
- ARL6IP1 | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV58614368; called by muse, mutect2, varscan2
- ARL6IP6 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV58442706; called by muse, mutect2, varscan2
- ARMC3 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV53060526; called by muse, mutect2, varscan2
- ARMC4 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 47/325 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1313755473; called by muse, mutect2, varscan2
- ARMC8 | c.1038+1G>A p.X346_splice (on ENST00000469044 / NM_001363941.2; = p.X332_splice on NM_014154.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 13/57 reads (23%) | catalogued as COSV61768275; called by muse, mutect2, varscan2
- ARMC8 | c.1256G>A p.R419Q (on ENST00000469044 / NM_001363941.2; = p.R405Q on NM_015396.6) | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV58618205; called by muse, mutect2, varscan2
- ARMC9 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV63019620; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.942C>A p.C314* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as COSV63437774; called by muse, mutect2, varscan2
- ARMH4 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV50763798; called by muse, mutect2, varscan2
- ARMH4 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV50763808; called by muse, mutect2, varscan2
- ARSA | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as rs1437253036, COSV53350364; called by muse, mutect2, varscan2
- ART4 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as rs770694825, COSV57450945; called by muse, mutect2, varscan2
- ARV1 | c.317T>G p.F106C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59617657; called by muse, mutect2, varscan2
- ASAH2 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 189/739 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272785683; called by muse, mutect2, varscan2
- ASAP2 | c.1355G>A p.G452D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55630650; called by muse, mutect2, varscan2
- ASB15 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 37/150 reads (25%) | catalogued as rs1237485684, COSV51923543; called by muse, mutect2, varscan2
- ASB6 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764592974, COSV52964890; called by muse, mutect2, varscan2
- ASCC3 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61225960, COSV61226528; called by muse, mutect2, varscan2
- ASCC3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752951712, COSV100225437, COSV61226544; called by muse, mutect2, varscan2
- ASH1L | c.7612C>T p.R2538C (on ENST00000368346 / NM_001366177.2; = p.R2533C on NM_018489.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs764902812, COSV64206824; called by muse, mutect2, varscan2
- ASH1L | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs755792596, COSV64207562; called by muse, mutect2, varscan2
- ASIC2 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV63304262; called by muse, mutect2, varscan2
- ASPM | c.8508G>T p.Q2836H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.615); catalogued as COSV54128884; called by muse, mutect2, varscan2
- ASPM | c.6034G>T p.E2012* | Nonsense Mutation (SNP) | VAF 22/100 reads (22%) | catalogued as COSV54128893; called by muse, mutect2, varscan2
- ASPN | c.582G>T p.M194I | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV100978690; called by muse, mutect2, varscan2
- ASTN1 | c.3769G>A p.E1257K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as rs538221544, COSV62495987; called by muse, mutect2, varscan2
- ASTN1 | c.1530G>A p.W510* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV56067580; called by muse, mutect2, varscan2
- ASTN1 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs778335758; called by muse, mutect2, varscan2
- ASXL2 | c.788G>T p.R263I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55458033; called by muse, mutect2, varscan2
- ASZ1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as COSV52912602, COSV52912960; called by muse, mutect2, varscan2
- ATAD2B | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.062); catalogued as rs770685420, COSV53197801; called by muse, mutect2, varscan2
- ATAD5 | c.1199G>T p.R400I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58973985; called by muse, mutect2, varscan2
- ATAD5 | c.5339C>T p.S1780L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149072088; called by muse, mutect2, varscan2
- ATCAY | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs1333578472; called by muse, mutect2
- ATF7IP | c.2158+2T>C p.X720_splice | Splice Site (SNP) | VAF 15/35 reads (43%) | catalogued as COSV53770069; called by muse, mutect2, varscan2
- ATF7IP | c.3293G>A p.R1098Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs775681477, COSV53770087; called by muse, mutect2, varscan2
- ATG101 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs553016999; called by muse, mutect2, varscan2
- ATG2B | c.5166C>A p.F1722L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55890176, COSV55892007; called by muse, mutect2, varscan2
- ATG9A | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.324); catalogued as COSV63444889; called by muse, mutect2, varscan2
- ATL1 | c.282+2T>C p.X94_splice | Splice Site (SNP) | VAF 14/52 reads (27%) | catalogued as COSV63296305; called by muse, mutect2, varscan2
- ATP11C | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs768342557, COSV59561768; called by muse, mutect2, varscan2
- ATP12A | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs149324896; called by mutect2, varscan2
- ATP13A5 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.275); catalogued as COSV60868697; called by muse, mutect2, varscan2
- ATP1A1 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269859843, COSV55190986; called by muse, varscan2
- ATP1A3 | c.1253C>T p.S418L (on ENST00000545399 / NM_001256214.2; = p.S405L on NM_152296.5) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs368489500; called by muse, mutect2, varscan2
- ATP1A3 | c.94C>T p.R32C (on ENST00000545399 / NM_001256214.2; = p.R19C on NM_152296.5) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs782229302, COSV57487195; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ATP1A4 | c.59G>T p.R20I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63626329; called by muse, mutect2, varscan2
- ATP2A1 | c.2356G>T p.A786S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV62869211; called by muse, mutect2, varscan2
- ATP2A2 | c.545-6G>A | Splice Region (SNP) | VAF 15/46 reads (33%) | catalogued as rs766741286; called by muse, mutect2, varscan2
- ATP2A2 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs748353664, COSV58043827; called by muse, mutect2, varscan2
- ATP2B1 | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs868200483, COSV53806925; called by muse, mutect2, varscan2
- ATP2B2 | c.1589C>T p.A530V (on ENST00000352432; = p.A496V on NM_001683.5) | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV59495261; called by muse, mutect2, varscan2
- ATP2B2 | c.920C>T p.A307V (on ENST00000352432; = p.A318V on NM_001001331.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.687); catalogued as rs747289941, COSV59500214; called by muse, varscan2
- ATP2B4 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs141117629; called by muse, mutect2, varscan2
- ATP2C1 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs768289092, COSV60755662; called by muse, mutect2, varscan2
- ATP4A | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs776970403, COSV52867547; called by muse, mutect2, varscan2
- ATP4A | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); catalogued as rs904563816, COSV52871892; called by muse, mutect2
- ATP6AP2 | c.1039C>T p.R347* (on ENST00000378438; = p.R348* on NM_005765.3) | Nonsense Mutation (SNP) | VAF 15/24 reads (63%) | catalogued as COSV65797151; called by muse, mutect2, varscan2
- ATP6V0D1 | c.538A>C p.I180L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.768); catalogued as COSV52097447, COSV52097554; called by muse, mutect2, varscan2
- ATP6V1H | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs770394341, COSV62218082; called by muse, mutect2, varscan2
- ATP8A1 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs749733890, COSV52533691; called by muse, mutect2, varscan2
- ATP8A2 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs535509828, COSV54936164, COSV99680731; called by muse, mutect2, varscan2
- ATP8A2 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200573494, COSV54938064; called by muse, mutect2, varscan2
- ATP8B1 | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as COSV52175211, COSV99377226; called by muse, mutect2, varscan2
- ATP9B | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768544807, COSV56949480; called by muse, mutect2, varscan2
- ATR | c.3044G>A p.R1015Q | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.372); catalogued as rs564283952, COSV63385583, COSV63386951; called by muse, mutect2, varscan2
- ATRN | c.862A>G p.T288A | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV53527204; called by muse, mutect2, varscan2
- ATRN | c.1118A>T p.D373V | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV53526394, COSV53527213; called by muse, mutect2, varscan2
- ATRX | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs781932965, COSV64874076; called by muse, mutect2, varscan2
- ATXN10 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV53295852; called by muse, mutect2, varscan2
- ATXN10 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs780302545, COSV53295863; called by muse, mutect2, varscan2
- AURKC | c.104+2T>C p.X35_splice (on ENST00000302804 / NM_001015878.2; = p.X1_splice on NM_003160.3) | Splice Site (SNP) | VAF 17/51 reads (33%) | catalogued as rs1056512140, COSV57138044; called by muse, mutect2, varscan2
- AURKC | c.328T>G p.F110V (on ENST00000302804 / NM_001015878.2; = p.F76V on NM_003160.3) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1437633992, COSV57138061; called by muse, mutect2, varscan2
- AUTS2 | c.660C>T p.F220= | Splice Region (SNP) | VAF 83/166 reads (50%) | catalogued as rs766569162, COSV61397410; called by muse, mutect2, varscan2
- AVEN | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as rs766300982, COSV60734025; called by muse, mutect2, varscan2
- AVPR1B | c.959T>C p.F320S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100899331, COSV65638372; called by muse, mutect2, varscan2
- AXDND1 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62641158; called by muse, mutect2, varscan2
- AXIN1 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51986612, COSV51992449; called by muse, mutect2, varscan2
- B2M | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 25/90 reads (28%) | catalogued as COSV62563116; called by muse, varscan2
- B2M | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV62563917; called by muse, varscan2
- B3GALT2 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs947842680, COSV66463992; called by muse, mutect2, varscan2
- B3GALT2 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs751156224, COSV66463997; called by muse, mutect2, varscan2
- B3GLCT | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1358436411, COSV58454867; called by muse, mutect2, varscan2
- B3GNT2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57344563, COSV57345487; called by muse, mutect2, varscan2
- B4GAT1 | c.1182G>T p.K394N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV60820014, COSV60820398; called by muse, mutect2, varscan2
- BAAT | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs764187428, COSV52288701; called by muse, mutect2, varscan2
- BACE1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs138644093; called by muse, mutect2, varscan2
- BACH1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750785692, COSV54518596; called by muse, mutect2, varscan2
- BAG4 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1450943909; called by muse, mutect2, varscan2
- BAHCC1 | c.3361G>A p.A1121T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs373553406; called by muse, mutect2, varscan2
- BAIAP2L2 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1300085477, COSV60201804; called by muse, mutect2, varscan2
- BAMBI | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs369743386; called by muse, mutect2, varscan2
- BANK1 | c.542G>T p.R181I | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV59842036; called by muse, mutect2, varscan2
- BANP | c.553G>A p.D185N (on ENST00000286122; = p.D154N on NM_017869.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs764132919, COSV53736890; called by muse, mutect2, varscan2
- BARHL1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.105); catalogued as rs763126000, COSV55037504; called by muse, mutect2, varscan2
- BATF3 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as rs1010837801, COSV54658164; called by muse, mutect2, varscan2
- BBS10 | c.1447A>G p.T483A | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV67913176; called by muse, mutect2, varscan2
- BBS4 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV51437694; called by muse, mutect2, varscan2
- BBS5 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV54751728; called by muse, mutect2, varscan2
- BCAR3 | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV53074603; called by muse, mutect2, varscan2
- BCAS3 | c.437G>T p.R146I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66405057, COSV66405116; called by muse, mutect2, varscan2
- BCAS3 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs373017732; called by muse, mutect2, varscan2
- BCAT1 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as COSV53909962, COSV53910679; called by muse, mutect2, varscan2
- BCAT2 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1294788307, COSV60272386; called by muse, mutect2, varscan2
- BCAT2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs886710460, COSV60272395; called by muse, mutect2, varscan2
- BCHE | c.146T>G p.F49C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); catalogued as COSV52256287; called by muse, mutect2, varscan2
- BCKDHB | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs933828560, COSV57511238; called by muse, mutect2, varscan2
- BCL11B | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV61735288; called by muse, mutect2, varscan2
- BCL6 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV51651649; called by muse, mutect2, varscan2
- BCL6B | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs770283128, COSV53427614; called by muse, mutect2, varscan2
- BCL9L | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758711667, COSV58310682; called by muse, mutect2, varscan2
- BCLAF1 | c.1473G>T p.K491N | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV62141807; called by muse, mutect2, varscan2
- BCR | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760268025, COSV59930707; called by mutect2, varscan2
- BDKRB1 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as COSV53706009, COSV53707383; called by muse, mutect2, varscan2
- BDNF | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1349681470, COSV59233092, COSV59234846; called by muse, mutect2, varscan2
- BEND6 | c.50G>T p.R17I | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.202); catalogued as COSV66068829; called by muse, mutect2, varscan2
- BEND6 | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV66068836; called by muse, mutect2, varscan2
- BEST3 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100437932; called by mutect2, varscan2
- BFSP2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs200874347, COSV56588428; called by muse, mutect2, varscan2
- BHLHE41 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV54378594; called by muse, mutect2, varscan2
- BHMT | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs147391267, COSV57154212; called by muse, mutect2, varscan2
- BHMT | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.848); catalogued as rs762015001, COSV57154220; called by muse, mutect2, varscan2
- BICRAL | c.1830C>A p.F610L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV58405065; called by muse, mutect2, varscan2
- BIRC3 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99680230; called by mutect2, varscan2
- BIRC6 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70196110; called by muse, mutect2, varscan2
- BIRC6 | c.5345G>A p.R1782Q | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1158247243, COSV70197748; called by muse, mutect2, varscan2
- BIRC6 | c.6579G>T p.K2193N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV70198545; called by muse, mutect2, varscan2
- BIRC6 | c.7066A>G p.K2356E | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1344806521, COSV70198549; called by muse, mutect2, varscan2
- BIRC6 | c.7255G>A p.E2419K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV70198552; called by muse, mutect2, varscan2
- BIRC6 | c.9797A>C p.K3266T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV70198556; called by muse, mutect2, varscan2
- BIRC6 | c.11041G>A p.D3681N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs773665748, COSV70198560; called by muse, mutect2, varscan2
- BLK | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52051459; called by muse, varscan2
- BLZF1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs138245508; called by muse, mutect2, varscan2
- BMP10 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.896); catalogued as COSV54895132; called by muse, mutect2, varscan2
- BMP2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs776834114, COSV66577307; called by muse, mutect2, varscan2
- BMP5 | c.276A>C p.E92D | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV63702895; called by muse, mutect2, varscan2
- BMP7 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs149261355; called by muse, mutect2, varscan2
- BMT2 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51776280; called by muse, mutect2, varscan2
- BNC2 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs565251984, COSV66142337; called by muse, mutect2, varscan2
- BNC2 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs376354558; called by muse, mutect2, varscan2
- BNC2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66140045; called by muse, mutect2, varscan2
- BNIP3L | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV66077891; called by muse, mutect2, varscan2
- BNIPL | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs587607488, COSV54845615; called by muse, mutect2, varscan2
- BOD1L1 | c.7153C>T p.R2385W | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs202239933, COSV50011030; called by muse, mutect2, varscan2
- BPIFA2 | c.708C>T p.V236= | Splice Region (SNP) | VAF 10/46 reads (22%) | catalogued as rs758307953, COSV53610927; called by muse, mutect2, varscan2
- BRAF | c.1740T>G p.H580Q (on ENST00000288602 / NM_001374244.1; = p.H540Q on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56158918; called by muse, mutect2, varscan2
- BRCC3 | c.140+2T>C p.X47_splice | Splice Site (SNP) | VAF 18/42 reads (43%) | catalogued as COSV57462411; called by muse, mutect2, varscan2
- BRINP2 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773810112, COSV64177191; called by muse, mutect2, varscan2
- BRINP3 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV100819096, COSV66522458; called by muse, mutect2, varscan2
- BRINP3 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV66521476; called by muse, mutect2, varscan2
- BRIP1 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781321, CM1411623, COSV51998688; ClinVar: uncertain significance; called by muse, varscan2
- BRIP1 | c.1288A>G p.I430V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV51998711; called by muse, mutect2, varscan2
- BROX | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as COSV61799249; called by muse, mutect2, varscan2
- BRWD1 | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as rs750289132, COSV60892937; called by muse, mutect2, varscan2
- BSN | c.3174G>T p.K1058N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56516845; called by muse, mutect2, varscan2
- BSN | c.10300G>A p.D3434N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs772204044, COSV56516853; called by muse, mutect2, varscan2
- BTBD1 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs758435230, COSV55602817, COSV99915766; called by muse, mutect2, varscan2
- BTBD18 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV53554125; called by mutect2, varscan2
- BTBD7 | c.3031C>T p.L1011F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV58285479; called by muse, mutect2, varscan2
- BTBD7 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as rs1198567556, COSV100597941, COSV58283311; called by muse, mutect2, varscan2
- BTBD7 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV54135116; called by muse, mutect2, varscan2
- BTRC | c.710C>A p.S237Y (on ENST00000370187 / NM_033637.4; = p.S201Y on NM_003939.5) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1310261380, COSV64560475, COSV64560754, COSV64563174; called by muse, varscan2
- BYSL | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs765781821, COSV57828419; called by muse, mutect2, varscan2
- C10orf82 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.341); catalogued as rs1340585033, COSV65024686; called by muse, mutect2, varscan2
- C11orf16 | c.983T>C p.M328T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs760367890; called by mutect2, varscan2
- C11orf65 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67597379; called by muse, mutect2, varscan2
- C11orf87 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59356778; called by muse, mutect2, varscan2
- C12orf40 | c.946A>C p.K316Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV61131716; called by muse, mutect2, varscan2
- C12orf40 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs749162690, COSV61133712; called by muse, mutect2, varscan2
- C12orf56 | c.398A>C p.K133T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.051); catalogued as COSV61486711; called by mutect2, varscan2
- C14orf39 | c.1364G>A p.R455K | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.352); catalogued as COSV58781496, COSV58781699; called by muse, mutect2, varscan2
- C16orf78 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54556148; called by muse, mutect2, varscan2
- C16orf96 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs146734619; called by muse, mutect2, varscan2
- C17orf64 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs772362348, COSV52256406; called by mutect2, varscan2
- C17orf64 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.451); catalogued as rs1456917549, COSV52256415, COSV52256516; called by muse, varscan2
- C19orf38 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs1048670411, COSV59000081; called by muse, mutect2
- C1orf112 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs371455881; called by muse, mutect2, varscan2
- C1orf56 | c.887G>T p.S296I | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV54846825; called by muse, mutect2, varscan2
- C1orf74 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1204565302, COSV50550905; called by muse, mutect2, varscan2
- C1orf87 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as COSV64596991; called by muse, mutect2, varscan2
- C20orf194 | c.2851C>T p.R951* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as rs1420572222; called by muse, mutect2, varscan2
- C20orf96 | c.234G>T p.K78N (on ENST00000360321 / NM_153269.3; = p.K77N on NM_080571.1) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV100826705, COSV64403470; called by muse, mutect2, varscan2
- C21orf62 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs781073580, COSV66671926; called by muse, mutect2, varscan2
- C21orf91 | c.808G>A p.E270K (on ENST00000284881 / NM_001100420.2; = p.E269K on NM_017447.4) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs75916355; called by muse, mutect2, varscan2
- C2CD5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61723360; called by muse, mutect2, varscan2
- C2CD5 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61724285; called by muse, mutect2, varscan2
- C2orf16 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368267439; called by muse, mutect2, varscan2
- C2orf76 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs374956671; called by mutect2, varscan2
- C2orf78 | c.2011C>T p.L671F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV68517413; called by muse, mutect2, varscan2
- C3 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV55571762; called by muse, mutect2, varscan2
- C3AR1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756745490, COSV50817573; called by muse, mutect2, varscan2
- C4BPA | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.654); catalogued as COSV65536270; called by muse, mutect2, varscan2
- C5orf22 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs755393777, COSV57598218; called by muse, mutect2, varscan2
- C5orf38 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV57410018; called by muse, mutect2, varscan2
- C6 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as rs778044260, COSV54706799; called by muse, mutect2, varscan2
- C6orf62 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.947); catalogued as rs957447903, COSV65290291; called by muse, mutect2, varscan2
- C7 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV57473700; called by muse, mutect2, varscan2
- C7orf31 | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs566065357, COSV52217060; called by muse, mutect2, varscan2
- C8orf34 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV61378083; called by muse, mutect2, varscan2
- C8orf34 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 31/106 reads (29%) | catalogued as COSV57402091, COSV57412799, COSV57415557; called by muse, mutect2, varscan2
- C8orf48 | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52046869; called by mutect2, varscan2
- C9orf131 | c.1409C>A p.S470* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV56610871, COSV56612686; called by muse, mutect2, varscan2
- C9orf153 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.239); catalogued as rs1189221878, COSV59251184; called by muse, mutect2, varscan2
- CA10 | c.717G>T p.M239I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV53347237; called by muse, mutect2
- CA14 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.161); catalogued as COSV52528904; called by muse, mutect2, varscan2
- CA3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs773052803, COSV99570671; called by muse, varscan2
- CABS1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | catalogued as COSV56733413, COSV56734740; called by muse, mutect2, varscan2
- CACNA1D | c.3622G>A p.E1208K (on ENST00000350061 / NM_001128840.3; = p.E1228K on NM_000720.4) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55445291; called by muse, mutect2, varscan2
- CACNA1D | c.3992G>A p.S1331N (on ENST00000350061 / NM_001128840.3; = p.S1351N on NM_000720.4) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); catalogued as COSV55445313; called by muse, mutect2, varscan2
- CACNA1D | c.4664G>A p.R1555Q (on ENST00000350061 / NM_001128840.3; = p.R1575Q on NM_000720.4) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs765670623, COSV55445331; called by muse, mutect2, varscan2
- CACNA1D | c.5414G>A p.R1805H (on ENST00000350061 / NM_001128840.3; = p.R1825H on NM_000720.4) | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.443); catalogued as rs754161736, COSV55445344; called by muse, mutect2, varscan2
- CACNA1E | c.6466C>T p.R2156C (on ENST00000367573 / NM_001205293.3; = p.R2113C on NM_000721.4) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62392066; called by mutect2, varscan2
- CACNA1F | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557111335, CM1514227, COSV59904176; called by muse, mutect2, varscan2
- CACNA1I | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480721748, COSV60802916; called by muse, mutect2, varscan2
- CACNA1S | c.4714C>T p.R1572C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1301119456, COSV62938346; called by muse, mutect2
- CACNA2D4 | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs200636614, COSV54949212; called by muse, mutect2, varscan2
- CACNB1 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as rs1284854955, COSV59998717; called by muse, mutect2, varscan2
- CACNB4 | c.886A>C p.I296L | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV52392994; called by muse, mutect2, varscan2
- CAD | c.4273C>T p.P1425S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53026313; called by muse, mutect2, varscan2
- CADM1 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59009046; called by muse, mutect2, varscan2
- CADM2 | c.520G>A p.E174K (on ENST00000407528 / NM_001167674.2; = p.E176K on NM_153184.4) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.183); catalogued as COSV67367415, COSV67371063, COSV99081108; called by muse, mutect2, varscan2
- CADPS2 | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV57361011; called by muse, mutect2, varscan2
- CADPS2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs753686489, COSV57361028; called by muse, mutect2, varscan2
- CALD1 | c.1478C>T p.S493L (on ENST00000361675 / NM_033138.4; = p.S238L on NM_004342.7) | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs201681214, COSV62647355; called by muse, mutect2, varscan2
- CALML5 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV66702509; called by muse, mutect2, varscan2
- CAMK1 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV56538510; called by muse, mutect2, varscan2
- CAMK1D | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs202177332, COSV66610725; called by muse, mutect2, varscan2
- CAMKK2 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs762984197, COSV61214383; called by muse, mutect2, varscan2
- CAMSAP2 | c.1991G>A p.R664Q (on ENST00000236925 / NM_001297707.2; = p.R653Q on NM_203459.3) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs748956832, COSV99374459; called by muse, mutect2, varscan2
- CAP2 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.527); catalogued as COSV100012633, COSV57731698; called by muse, varscan2
- CAPN13 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54430097, COSV54436213; called by muse, mutect2, varscan2
- CAPRIN2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1279171030, COSV51831414, COSV51832203; called by muse, mutect2, varscan2
- CAPS2 | c.1221-1G>T p.X407_splice | Splice Site (SNP) | VAF 11/56 reads (20%) | catalogued as COSV60825209; called by muse, mutect2, varscan2
- CAPZA3 | c.778C>A p.L260I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56848343, COSV56851939; called by muse, mutect2, varscan2
- CARD18 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as rs377022898, COSV73233165; called by muse, mutect2, varscan2
- CARNMT1 | c.1093A>C p.K365Q | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.478); catalogued as COSV65193526; called by muse, mutect2, varscan2
- CASP5 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs747113465, COSV52828282; called by muse, mutect2, varscan2
- CASP7 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs965965084, COSV61881624; called by muse, mutect2, varscan2
- CASZ1 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59734901; called by muse, mutect2, varscan2
- CATSPERB | c.1265T>G p.F422C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV56425699; called by muse, mutect2, varscan2
- CATSPERD | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs370820146, COSV101062622, COSV67534523; called by muse, mutect2, varscan2
- CATSPERD | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs774298301, COSV58465150, COSV58466015; called by muse, mutect2, varscan2
- CAVIN2 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58423992; called by muse, mutect2, varscan2
- CBFA2T3 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs760316068, COSV51933331; called by muse, mutect2, varscan2
- CBL | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs1228155346, COSV50635470; called by muse, mutect2, varscan2
- CBL | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV50635508; called by muse, mutect2, varscan2
- CBL | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755244263, COSV50633583; called by mutect2, varscan2
- CBX7 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs768808588, COSV53358944; called by muse, mutect2, varscan2
- CBY2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.09); catalogued as rs761413589, COSV60117619; called by muse, mutect2, varscan2
- CC2D2A | c.3154G>A p.D1052N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.496); catalogued as rs1055487228, COSV67503381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC110 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 38/147 reads (26%) | catalogued as COSV56872519; called by muse, mutect2, varscan2
- CCDC112 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 38/154 reads (25%) | catalogued as COSV65473048; called by muse, mutect2, varscan2
- CCDC130 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55582961; called by muse, mutect2, varscan2
- CCDC138 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150930591, COSV54570938; called by muse, mutect2, varscan2
- CCDC141 | c.876G>T p.E292D | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs1003474378, COSV69458978; called by muse, mutect2, varscan2
- CCDC144A | c.2423C>A p.S808Y | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV60697972; called by muse, varscan2
- CCDC144A | c.3158G>A p.R1053Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as rs199644397; called by muse, mutect2, varscan2
- CCDC146 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV53547405; called by muse, mutect2, varscan2
- CCDC15 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV61081425; called by muse, varscan2
- CCDC15 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 40/140 reads (29%) | catalogued as rs368208768; called by muse, mutect2, varscan2
- CCDC158 | c.3272C>T p.S1091F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52953616, COSV52953739; called by muse, mutect2, varscan2
- CCDC158 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs17001889, COSV66355742; called by muse, mutect2, varscan2
- CCDC159 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.889); catalogued as rs200265497; called by muse, mutect2, varscan2
- CCDC168 | c.21131G>T p.R7044I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59420367; called by muse, mutect2, varscan2
- CCDC168 | c.16759C>A p.L5587I | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); catalogued as COSV59421290; called by muse, varscan2
- CCDC168 | c.16754G>A p.R5585Q | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs760443346, COSV59421301; called by muse, varscan2
- CCDC168 | c.16556C>T p.S5519L | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as COSV59421311; called by muse, mutect2, varscan2
- CCDC168 | c.16226G>A p.G5409E | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.018); catalogued as COSV59421321; called by muse, mutect2, varscan2
- CCDC168 | c.16129G>A p.D5377N | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.975); catalogued as rs993878572, COSV59421337; called by muse, varscan2
- CCDC168 | c.15676A>C p.I5226L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.145); catalogued as COSV59421345; called by muse, mutect2, varscan2
- CCDC168 | c.15530A>C p.D5177A | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as COSV59421361; called by muse, mutect2, varscan2
- CCDC168 | c.14962G>A p.A4988T | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs1566406027, COSV59421383; called by muse, mutect2, varscan2
- CCDC168 | c.13915A>C p.N4639H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as COSV59421398; called by muse, mutect2, varscan2
- CCDC168 | c.8789C>T p.S2930F | Missense Mutation (SNP) | VAF 86/387 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV70555042; called by muse, mutect2, varscan2
- CCDC168 | c.4161G>T p.K1387N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1266012070; called by muse, mutect2, varscan2
- CCDC168 | c.2139G>T p.M713I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV70555044; called by muse, mutect2
- CCDC170 | c.1916C>A p.S639Y | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV53340031; called by muse, mutect2, varscan2
- CCDC171 | c.343A>C p.K115Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV52640489; called by muse, mutect2, varscan2
- CCDC173 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as rs1202256987, COSV69572849; called by muse, mutect2, varscan2
- CCDC174 | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs761797850, COSV57980753; called by muse, mutect2, varscan2
- CCDC178 | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55771352; called by muse, varscan2
- CCDC180 | c.191C>A p.S64Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV63829621; called by muse, mutect2, varscan2
- CCDC180 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs767399271, COSV63829635; called by mutect2, varscan2
- CCDC180 | c.3370A>G p.T1124A | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as COSV63829645; called by muse, mutect2, varscan2
- CCDC30 | c.2088G>T p.K696N (on ENST00000340612; = p.K653N on NM_001080850.3) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.185); catalogued as COSV59606185; called by muse, mutect2, varscan2
- CCDC33 | c.186G>A p.V62= | Splice Region (SNP) | VAF 11/23 reads (48%) | catalogued as COSV58351023; called by muse, mutect2, varscan2
- CCDC50 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV66667794; called by muse, mutect2, varscan2
- CCDC50 | c.996G>A p.M332I (on ENST00000392455 / NM_178335.3; = p.M156I on NM_174908.4) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs769046221, COSV101165320; called by muse, mutect2, varscan2
- CCDC70 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146304026; called by muse, mutect2, varscan2
- CCDC73 | c.2371G>T p.D791Y | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV58797891; called by muse, mutect2, varscan2
- CCDC73 | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as COSV58797895; called by muse, mutect2, varscan2
- CCDC80 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52816453; called by muse, mutect2, varscan2
- CCDC81 | c.425A>C p.Q142P | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as COSV53578024; called by muse, mutect2, varscan2
- CCDC83 | c.1019G>A p.G340D (on ENST00000342404 / NM_001286159.2; = p.G371D on NM_173556.5) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV54701498; called by muse, mutect2, varscan2
- CCDC88A | c.4999C>T p.R1667* (on ENST00000436346 / NM_001365480.1; = p.R1639* on NM_018084.5) | Nonsense Mutation (SNP) | VAF 23/116 reads (20%) | catalogued as rs1409064207, COSV55060707; called by muse, mutect2, varscan2
- CCDC88A | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs769621745, COSV55069328; called by muse, mutect2
- CCDC90B | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as rs148744063, COSV52623726; called by muse, mutect2, varscan2
- CCIN | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.832); catalogued as rs369124897, COSV58724434; called by mutect2, varscan2
- CCL16 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs199602184; called by muse, mutect2, varscan2
- CCL27 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as rs777698595, COSV52404933; called by muse, mutect2, varscan2
- CCNI | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as COSV52959632; called by muse, mutect2, varscan2
- CCNY | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV55184575; called by muse, mutect2, varscan2
- CCP110 | c.2805G>T p.K935N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66816902; called by muse, mutect2, varscan2
- CCPG1 | c.1002G>T p.Q334H | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60525072, COSV60527497; called by muse, mutect2, varscan2
- CCPG1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60525082; called by muse, mutect2, varscan2
- CCR2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); catalogued as rs539087679, COSV52748389; called by muse, mutect2, varscan2
- CCR4 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs200003145; called by muse, mutect2, varscan2
- CCR5 | c.789C>A p.F263L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV52751470; called by mutect2, varscan2
- CCSER1 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.06); catalogued as rs1162759832, COSV61418488; called by muse, varscan2
- CCSER1 | c.2362C>A p.L788I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV100391524, COSV61426200; called by muse, varscan2
- CCSER2 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.271); catalogued as rs370948089, COSV56504758; called by muse, mutect2, varscan2
- CCSER2 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs774031266, COSV56503754; called by muse, mutect2, varscan2
- CCSER2 | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.786); catalogued as rs751772415, COSV56502329; called by muse, mutect2, varscan2
- CCT3 | c.1150C>A p.L384I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.665); catalogued as rs746203604, COSV55288703; called by mutect2, varscan2
- CCT8L2 | c.1507G>T p.G503* | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | catalogued as COSV63462245, COSV63463775; called by muse, mutect2, varscan2
- CD109 | c.3724G>A p.A1242T | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54648743; called by muse, varscan2
- CD177 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs541810499, COSV100946081; called by mutect2, varscan2
- CD200 | c.569G>A p.R190H (on ENST00000473539 / NM_001004196.3; = p.R165H on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs759307241, COSV59862577; called by muse, mutect2, varscan2
- CD200R1L | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as rs369844409; called by muse, mutect2, varscan2
- CD244 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV59237419; called by muse, mutect2, varscan2
- CD247 | c.463G>A p.A155T (on ENST00000362089 / NM_198053.3; = p.A154T on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs561262982, COSV54816287; called by muse, mutect2, varscan2
- CD2AP | c.1009-1G>T p.X337_splice | Splice Site (SNP) | VAF 33/138 reads (24%) | catalogued as COSV63760515; called by muse, mutect2, varscan2
- CD300E | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60790410; called by muse, mutect2, varscan2
- CD33 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV51801343; called by muse, mutect2, varscan2
- CD34 | c.867G>T p.K289N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60412789; called by muse, mutect2, varscan2
- CD40 | c.505A>C p.T169P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.184); catalogued as COSV64847729; called by muse, mutect2, varscan2
- CD48 | c.571T>A p.S191T | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63566483; called by muse, mutect2, varscan2
- CD58 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV59841443; called by muse, mutect2, varscan2
- CD59 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV100681179, COSV60919262; called by muse, mutect2, varscan2
- CD5L | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as COSV63821845; called by muse, mutect2, varscan2
- CD80 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 26/107 reads (24%) | catalogued as COSV51802158; called by muse, mutect2, varscan2
- CD93 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as rs762071141, COSV55669405, COSV99848760; called by mutect2, varscan2
- CDC14B | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373460925; called by muse, mutect2, varscan2
- CDC16 | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as rs749424782, COSV52959332; called by mutect2, varscan2
- CDC20B | c.543A>C p.K181N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV57051797; called by muse, mutect2, varscan2
- CDC25C | c.1107G>T p.K369N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60399180; called by muse, mutect2, varscan2
- CDC37L1 | c.437G>T p.R146I | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs750184463, COSV67865969; called by muse, mutect2, varscan2
- CDC40 | c.1473G>T p.Q491H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV57009263; called by muse, mutect2, varscan2
- CDC42BPA | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV62007847; called by muse, mutect2, varscan2
- CDC42BPG | c.4401G>T p.E1467D | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs776034595, COSV61347081; called by muse, mutect2, varscan2
- CDC45 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV54245044; called by muse, mutect2, varscan2
- CDC5L | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV65175931; called by muse, mutect2, varscan2
- CDC6 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as rs762281243, COSV52930356; called by muse, mutect2, varscan2
- CDC73 | c.320G>T p.S107I | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV66466617; called by muse, mutect2, varscan2
- CDC73 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV66465795; called by muse, mutect2, varscan2
- CDC73 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV66465307, COSV66466222; called by muse, varscan2
- CDH10 | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV52573828, COSV52579029; called by muse, mutect2, varscan2
- CDH11 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0.011); catalogued as rs373610980; called by muse, mutect2, varscan2
- CDH12 | c.43T>C p.F15L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.048); catalogued as COSV66401364; called by muse, varscan2
- CDH15 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.943); catalogued as rs763753067, COSV57021649; called by mutect2, varscan2
- CDH24 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52975725; called by muse, mutect2, varscan2
- CDH8 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54846434; called by muse, mutect2, varscan2
- CDH8 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV54864663; called by muse, mutect2, varscan2
- CDHR3 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs144538079; called by muse, mutect2, varscan2
- CDK12 | c.3146G>A p.R1049H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751631029, COSV71000444; called by muse, mutect2, varscan2
- CDK13 | c.4094G>A p.R1365Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1257385562, COSV51699186; called by muse, mutect2, varscan2
- CDK8 | c.471T>G p.I157M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67420401; called by muse, mutect2, varscan2
- CDK8 | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV67420037; called by muse, mutect2, varscan2
- CDKL5 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1466254546, COSV66111058; called by muse, mutect2, varscan2
- CDON | c.1894C>T p.R632* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as rs752726620, COSV54997436; called by mutect2, varscan2
- CDRT1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV55413948; called by muse, mutect2
- CDS1 | c.642C>T p.F214= | Splice Region (SNP) | VAF 4/21 reads (19%) | catalogued as rs375840719; called by mutect2, varscan2
- CDX4 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs760648974, COSV65171429; called by muse, mutect2, varscan2
- CEL | c.1073G>A p.G358D (on ENST00000673714; = p.G355D on NM_001807.6) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751226585, COSV100672856; called by mutect2, varscan2
- CELSR1 | c.6799G>A p.D2267N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs149238203, COSV99417587; called by muse, mutect2, varscan2
- CEMIP | c.1554C>A p.F518L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV54991814; called by muse, mutect2, varscan2
- CENPF | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs376653860; called by muse, mutect2, varscan2
- CENPF | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV65274528; called by muse, mutect2, varscan2
- CENPF | c.8533G>T p.E2845* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV65273276; called by muse, mutect2, varscan2
- CENPO | c.288G>T p.E96D | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV53173115; called by muse, mutect2, varscan2
- CEP104 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs754082531, COSV65517159; called by muse, mutect2, varscan2
- CEP104 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as rs145420390, COSV65511801; called by muse, mutect2, varscan2
- CEP104 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs757772764, COSV65511804; called by muse, mutect2, varscan2
- CEP112 | c.2711G>A p.R904Q (on ENST00000392769 / NM_001353127.1; = p.R160Q on NM_001037325.3) | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as rs375574894, COSV100439458; called by muse, mutect2, varscan2
- CEP126 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | catalogued as rs757264461, COSV54822167; called by muse, mutect2, varscan2
- CEP128 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs1322517906, COSV53674277; called by muse, mutect2, varscan2
- CEP135 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.581); catalogued as rs766191061, COSV57259680; called by muse, mutect2, varscan2
- CEP152 | c.2960G>A p.R987Q | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755071182, COSV57858956; called by muse, mutect2, varscan2
- CEP162 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs138324166, COSV57617396; called by muse, mutect2, varscan2
- CEP162 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779413417, COSV57619469; called by muse, mutect2, varscan2
- CEP164 | c.2857C>T p.R953W | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs767099855, COSV54046819; called by muse, mutect2, varscan2
- CEP192 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV58063241; called by muse, mutect2, varscan2
- CEP192 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs956353932, COSV58063247; called by muse, mutect2, varscan2
- CEP192 | c.3593G>A p.R1198K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV58063255; called by muse, mutect2, varscan2
- CEP192 | c.5665G>A p.V1889I | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs768565025, COSV58063273; called by muse, mutect2, varscan2
- CEP192 | c.7540T>G p.L2514V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.376); catalogued as COSV58063289; called by muse, mutect2, varscan2
5,602 further variants in this file (3,855 protein-altering or splice-affecting, 1,254 silent, 493 other) are not listed here.
